Somatic mutation profile of tumor specimen TCGA-CQ-A4CH-01A (aliquot TCGA-CQ-A4CH-01A-11D-A25Y-08) from TCGA case TCGA-CQ-A4CH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Border of tongue; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 58.7 years (21,455 days).
Specimen TCGA-CQ-A4CH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6181efb3-fd0b-4b1d-b259-228a22bd2bbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-A4CH-10A (Blood Derived Normal), aliquot TCGA-CQ-A4CH-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2a602ac-6453-4734-9a24-0189623ae40d

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP6 | c.3544G>A p.V1182I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as rs374551617; called by muse, mutect2, varscan2
- FZD9 | c.1601T>C p.F534S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs1554563646, COSV100289592; called by muse, mutect2
- GRK1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.187); catalogued as COSV100175242; called by muse, mutect2, varscan2
- IQGAP3 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100752068; called by muse, mutect2
- MARCHF4 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1214830803, COSV56102656; called by muse, mutect2
- MTHFD1L | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1403489543, COSV100944854; called by muse, mutect2
- NEUROD1 | c.310A>C p.M104L | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs943924773, COSV99716796; called by muse, mutect2
- PCDHGC4 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 12/172 reads (7%) | catalogued as rs1307620045, COSV52744476, COSV52748730; called by muse, mutect2
- SI | c.2005-1G>A p.X669_splice | Splice Site (SNP) | VAF 8/125 reads (6%) | catalogued as COSV100014079, COSV100015434; called by muse, mutect2
- SLC46A3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs759574136, COSV57180509; called by muse, mutect2
- ZFP57 | c.1219C>A p.L407I | Missense Mutation (SNP) | VAF 33/428 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100971815; called by muse, mutect2
- TP53 | c.93del p.L32Cfs*12 | Frame Shift Del (DEL) | VAF 9/89 reads (10%) | called by mutect2, pindel, varscan2
- OMP | c.363C>T p.D121= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as rs782518243, COSV99581575; called by muse, mutect2
- SCN8A | c.2358T>A p.A786= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV100633263; called by muse, mutect2, varscan2
- THOC2 | c.2928A>G p.K976= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99832761; called by muse, mutect2, varscan2
- ZNF616 | c.624T>C p.T208= | Silent (SNP) | VAF 7/178 reads (4%) | called by muse, mutect2
- UQCR10 | c.150+18C>T | Intron (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100340772, COSV100340778; called by muse, mutect2, varscan2
